Surgical pathology report (de-identified scan), TCGA case TCGA-96-7545, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - NYU, specimen TCGA-96-7545-01A (Primary Tumor).

[page 1 of 2]
COLLECTION DATE: [REDACTED]

SPECIMENS:

1. FS-PULMONARY NODULE
2. 6TH RIB

DIAGNOSIS:

1. LUNG, RIGHT, NODULE: WEDGE RESECTION

- MODERATELY DIFFERENTIATED ADENOCARCINOMA (1.1 CM), INVASIVE OF OVERLYING PLEURA.
- BENIGN INTRAPULMONARY LYMPH NODE, NEGATIVE FOR CARCINOMA.
- MARGIN OF RESECTION, NEGATIVE FOR CARCINOMA.

2. RIB, SIXTH: RESECTION

- SEGMENT OF RIB, NEGATIVE FOR CARCINOMA.

COMMENT: The tumor displays a predominantly acinar pattern associated with scar and small papillary and peripheral bronchioloalveolar components. Examination of elastic stains supports the finding of pleural invasion. No lymphovascular invasion is seen. The tumor is TTF1 positive and shows histologic similarity to the patient's prior left upper lobe carcinoma [REDACTED]. This case has been reviewed at the intradepartmental daily consensus meeting.

[REDACTED]
Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

Lung nodule right, R/O carcinoma

MACROSCOPIC DESCRIPTION:

The specimen is received fresh in two parts, each labeled with the patient's name.

1. Part one is labeled 'pulmonary nodule.' It consists of a 4 x 3 x 1.5 cm wedge resection of lung. The pleural surface is smooth tan red and glistening. It has been previously incised to reveal a 1.1 x 0.8 x 0.7 cm tan white fairly well circumscribed firm mass, 0.3 cm from the stapled margin. The pleural surface in the area of the tumor is inked blue. The pleura near the stapled margin is inked black. Representative section is taken and submitted for frozen section. After frozen section the specimen is entirely submitted.

[page 2 of 2]
2. Part two is labeled 'sixth rib.' It consists of a 10.5 x 2.0 x 0.6 cm segment of rib. The specimen is serially sectioned to reveal no gross lesions. Representative sections are submitted after decalcification.

[REDACTED]

SUMMARY OF SECTIONS:

1A frozen section control
1B rest of tumor
1C stapled margin
1D-H remainder of specimen
2A-B representative

SPECIAL PROCEDURES:

TTF1, elastic

INTRA - OPERATIVE CONSULTATION:

1. Pulmonary nodule; frozen section

Adenocarcinoma. Results reported [REDACTED]
[REDACTED]

Intra-Operative Consultation #1 performed by

[REDACTED]

Final Diagnosis performed by

[REDACTED]

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by [REDACTED]

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 2e2514e4-71b8-48e3-823e-7daa63911a20 (TCGA-96-7545.C3A70C66-AE03-435F-A2E7-05AF6A9F0759.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).